Surgical pathology report (de-identified scan), TCGA case TCGA-XJ-A9DX, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Kansas, specimen TCGA-XJ-A9DX-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

NAME:		SURG PATH #:
MR #:		SPECIMEN CLASS:
BILLING #:		ALT ID #:
LOCATION:		DATE OF PROCEDURE:
AGE:	SEX: M	DATE RECEIVED:
DOB:		TIME RECEIVED:
PHYSICIAN:		DATE OF REPORT:
COPY TO:		DATE OF PRINTING:

Material Received:

A: prostate
B: right external iliac lymph node
C: right obturator lymph node
D: right hypogastric lymph node
E: left external iliac lymph node
F: left obturator lymph node
G: left hypogastric lymph node
H: Hernia sac

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS 861.9
J 6/5/14

History:

ear-old male with a clinical history of prostate cancer.

Final Diagnosis:

- A. Prostate, prostatectomy:
Prostatic adenocarcinoma, Gleason grade 5 + 4 (score 9/10). See comment.
- B. Lymph nodes (6), "right external iliac lymph node", dissection:
There is no evidence of malignancy in six lymph nodes (0/6).
- C. Lymph nodes (2), "right obturator lymph node", biopsy:
There is no evidence of malignancy in two lymph nodes (0/2).
- D. Lymph nodes (2), "right hypogastric lymph node", biopsy:
There is metastatic adenocarcinoma in 1 of 2 lymph nodes (1/2).
- E. Lymph nodes (6), "left external iliac lymph node", dissection:
There is no evidence of malignancy in six lymph nodes (0/6).
- F. Lymph nodes (4), "left obturator lymph node", dissection:
There is no evidence of malignancy in four lymph nodes (0/4).
- G. Lymph node (2), "left hypogastric lymph node", biopsy:
There is metastatic adenocarcinoma in 1 of 2 lymph nodes (1/2) with extracapsular extension.
- H. Mesothelial lined fibrous tissue, "hernia sac", excision:
Hernia sac.

MR #:

Page 1 of 4

Date of Printing:

SURGICAL PATHOLOGY REPORT

Order Number:

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Comment:

PROSTATE CANCER CHECKLIST:

Procedure: Robotic assisted laparoscopic prostatectomy

Histologic Type: Adenocarcinoma

Histologic Grade: Poorly differentiated

Gleason Pattern

Primary Pattern: 5

Secondary Pattern: 4

Total Gleason Score: 9

Proportion (percentage) of prostatic tissue involved by tumor: 60 %

Extraprostatic Extension: Present

Seminal Vesicle Invasion: Present

Margins: Right and left posterior resection margins are involved by tumor, including the seminal right seminal vesicle margin

Treatment Effect on Carcinoma: Not applicable

Lymph-Vascular Invasion: Present

Lymph Nodes:

Number Examined: 22

Number Involved: 2

Size of largest lymph node metastasis: 4 mm

Perineural Invasion: Present

Additional Pathologic Findings: None

Pathologic Staging (pTNM):

pT3bN1M n/a

Primary Tumor (pT)

pT3: Extraprostatic extension

pT3a: Extraprostatic extension or microscopic invasion of bladder neck

pT3b: Seminal vesicle invasion

Regional Lymph Nodes (pN)

pN1: Metastasis in regional lymph node or nodes

Distant Metastasis (pM)

Not applicable

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Pursuant to the Quality Assurance Program at _____ this case has been concurrently reviewed by the following
pathologist: Dr. _____ who agrees with the above diagnosis.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By

Interpreted by:

Gross Description:

A. Received fresh labeled with the patient's name and "prostate" is a 68 gram prostate measuring 5.2 cm from right to left, 5.7 cm from anterior to posterior, and 3.9 cm from superior to inferior. The right seminal vesicle measures 3.8 x 1.9 x 0.9 cm, the right vas deferens measures 4.3 cm in length and 0.4 cm in diameter, the left vas deferens measures 3.9 cm in length and 0.5 cm in diameter and the left seminal vesicle measures 3.0 x 1.4 x 0.7 cm. The external surface of the prostate is tan-pink and primarily

MR #:

Page 2 of 4

Date of Printing:

SURGICAL PATHOLOGY REPORT

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

ragged. The right side of the prostate is inked black and the left side is inked orange. The prostate is serially sectioned to reveal a tan-brown nodular cut surface. The specimen is submitted as follows:

- A1 Right bladder neck margin.
- A2 Left bladder neck margin.
- A3 Right distal urethral margin.
- A4 Left distal urethral margins.
- A5 Right seminal vesicle and vas deferens margin.
- A6 Left seminal vesicle and vas deferens margin.
- A7 Representative section from the right mid-anterior prostate.
- A8 Representative section from the left mid-anterior prostate.
- A9-A16 Every other section from the posterior right lobe from apex to base (A12 and A13 is one section bisected; A14 and A15 is one section bisected).
- A17-A24 Every other section from the posterior left lobe from apex to base (A21 and A22 is one section bisected; A23 and A24 is one section bisected).

B. Received in formalin labeled with the patient's name and "right external iliac lymph node" is a 4.9 x 4.6 x 1.1 cm aggregate of yellow-tan fibroadipose tissue that is palpated to reveal six possible lymph nodes ranging in size from 0.2 x 0.2 x 0.2 cm to 2.0 x 1.0 x 0.6 cm. The specimen is submitted as follows:

- B1 Two possible lymph nodes.
- B2 Three possible lymph nodes.
- B3 One possible lymph node, bisected.

C. Received in formalin labeled with the patient's name and "right obturator lymph node" is a 6.9 x 2.2 x 1.4 cm aggregate of yellow-tan fibroadipose tissue that is palpated to reveal two possible lymph nodes measuring 2.1 x 1.4 x 1.0 cm and 2.3 x 1.4 x 0.8 cm. The specimen is submitted as follows:

- C1 One possible lymph node, bisected.
- C2 One possible lymph node, bisected.

D. Received in formalin labeled with the patient's name and "right hypogastric lymph node" is a 3.4 x 2.8 x 0.7 cm aggregate of yellow-tan fibroadipose tissue that is palpated to reveal two possible lymph nodes measuring 1.1 x 0.9 x 0.4 cm and 1.9 x 1.1 x 0.6 cm. The specimen is submitted as follows:

- D1 One possible lymph node.
- D2 One possible lymph node.

E. Received in formalin labeled with the patient's name and "left external iliac lymph node" is a 5.2 x 3.1 x 0.9 cm aggregate of yellow-tan fibroadipose tissue that is palpated to reveal six possible lymph nodes ranging in size from 0.5 x 0.4 x 0.4 cm to 1.3 x 1.2 x 0.7 cm. The specimen is submitted as follows:

- E1 Three possible lymph nodes.
- E2 Three possible lymph nodes.
- E3 One possible lymph node, bisected.

F. Received in formalin labeled with the patient's name and "left obturator lymph node" is a 5.7 x 4.2 x 1.0 cm aggregate of yellow-tan fibroadipose tissue that is palpated to reveal four possible lymph nodes ranging in size from 0.3 x 0.3 x 0.3 cm to 1.7 x 1.0 x 0.9 cm. The specimen is submitted as follows:

- F1 Three possible lymph nodes.
- F2 One possible lymph node, bisected.

G. Received in formalin labeled with the patient's name and "left hypogastric lymph node" is a 3.9 x 3.5 x 1.3 cm aggregate of yellow-tan fibroadipose tissue that is palpated to reveal two possible lymph nodes measuring 2.0 x 1.4 x 0.6 cm and 3.4 x 1.4 x 0.6 cm. The specimen is submitted as follows:

- G1 One possible lymph node.
- G2-G3 One possible lymph node, bisected.

H. Received in formalin labeled with the patient's name and "hernia sac" is a 4.2 x 1.8 x 0.8 cm irregular piece of tan-brown tissue. The tissue is serially sectioned and no gross abnormalities are identified. Representative sections are submitted in cassette H1.

MR #:

Page 3 of 4

Date of Printing:

SURGICAL PATHOLOGY REPORT

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Dual/Synchronous Primary	Noted	

MR #:

Page 4 of 4

Date of Printing:

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 2eea2de3-93a6-4373-9780-def36319f957 (TCGA-XJ-A9DX.FB120749-2C3B-4760-82F2-73C630BF0346.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).